Gene-level copy-number profile of tumor specimen TCGA-MA-AA43-01A from TCGA case TCGA-MA-AA43, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.3 years (17,658 days).
Specimen TCGA-MA-AA43-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5d7ac947-eb86-4118-bd9a-42fbd5aa91f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MA-AA43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95ee8b5e-4171-4f43-b9e3-c2e3b3fd963c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,601; copy number 3: 22,158; copy number 4: 15,629; copy number 5: 6,962; copy number 6: 3,556; copy number 7: 2,330; copy number 8: 681; copy number 9: 889; copy number 41: 4; copy number 85: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MA-AA43-01A-11D-A42N-01): tumor purity 0.52, ploidy 3.57, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,913 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–2,262,023, 79 genes, copy number 7–9 (broad region; genes not listed).
- chr5:5,688,805–6,707,711, 14 genes, copy number 8: AC026736.1, AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102.
- chr5:7,272,792–7,391,907, 9 genes, copy number 85: AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:21,750,673–23,689,386, 15 genes, copy number 7: CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr5:31,053,565–37,249,421, 116 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr5:50,396,192–50,443,248, 1 gene, copy number 9: EMB.
- chr5:52,673,186–56,233,330, 78 genes, copy number 7 (broad region; genes not listed).
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 7–8 (broad region; genes not listed).
- chr17:39,687,914–39,747,291, 4 genes, copy number 41 (within-gene range 5–41): ERBB2, MIR4728, MIEN1, GRB7.
- chr20:4,731,279–64,313,132, 1,312 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
